Somatic mutation profile of tumor specimen TCGA-90-A4EE-01A (aliquot TCGA-90-A4EE-01A-11D-A257-08) from TCGA case TCGA-90-A4EE, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.9 years (19,676 days).
Specimen TCGA-90-A4EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b00d62b-368d-4858-8f4e-d8332fe346df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-A4EE-10B (Blood Derived Normal), aliquot TCGA-90-A4EE-10B-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fd4e209-8dab-4d2f-ab8c-a0363d691fc3

The open-access MAF lists 383 somatic variants for this specimen: 296 protein-altering or splice-affecting, 76 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 76, Nonsense Mutation 28, Splice Site 7, RNA 5, Frame Shift Del 5, 3'UTR 3, Frame Shift Ins 3, 5'Flank 2, Translation Start Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4634+1G>C p.X1545_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100933094; called by muse, mutect2
- ABCA9 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100382713, COSV60625057; called by muse, mutect2, varscan2
- ABHD8 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); catalogued as COSV99395467; called by muse, mutect2
- ACACB | c.5054G>T p.G1685V | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100622687; called by muse, mutect2, varscan2
- ACAD9 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459096; called by muse, mutect2, varscan2
- ACCS | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV99772777; called by muse, mutect2, varscan2
- ADAM18 | c.345G>T p.R115S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99695339; called by muse, mutect2, varscan2
- ADAMTS10 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54360864; called by muse, mutect2, varscan2
- ADAMTS12 | c.2029G>A p.G677S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1440202622, COSV100710652; called by muse, mutect2, varscan2
- ADAMTS16 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs115892769; called by muse, mutect2, varscan2
- ADGRB1 | c.4031G>A p.S1344N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as COSV100029490; called by muse, mutect2, varscan2
- ADRA1A | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV99370575; called by muse, mutect2, varscan2
- AHNAK2 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100316899; called by muse, mutect2, varscan2
- AIFM1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780933; called by muse, mutect2, varscan2
- AMZ1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs370233879, COSV56688035; called by muse, mutect2, varscan2
- ANKFN1 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100593343; called by muse, mutect2, varscan2
- ANO1 | c.1400T>A p.L467Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.3); catalogued as COSV100303890; called by muse, mutect2, varscan2
- APOL2 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969091; called by muse, mutect2, varscan2
- ARFGEF2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100904205; called by muse, mutect2, varscan2
- ARHGAP11A | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV100853214; called by muse, mutect2, varscan2
- ARHGAP20 | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99503672; called by muse, mutect2
- ARID1B | c.4703A>G p.Q1568R | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.196); catalogued as COSV99268463; called by muse, mutect2, varscan2
- ARID2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 56/268 reads (21%) | catalogued as COSV57596554, COSV57617903; called by muse, varscan2
- ARID2 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100535897; called by muse, varscan2
- ASMT | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101172435, COSV67110460; called by muse, mutect2, varscan2
- ATP1A2 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100767748, COSV63405647; called by muse, mutect2, varscan2
- ATP1A4 | c.1910T>C p.V637A | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV100927502; called by muse, mutect2, varscan2
- ATRNL1 | c.4127G>T p.G1376V | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370145, COSV58092217; called by muse, mutect2, varscan2
- AVEN | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100145441; called by muse, mutect2, varscan2
- BHMT | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV57154280, COSV99165375; called by muse, mutect2, varscan2
- BPIFB3 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV100972336; called by muse, mutect2, varscan2
- BPTF | c.6661C>G p.Q2221E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1568126386, COSV100074641; called by muse, mutect2, varscan2
- C1orf43 | c.519G>C p.Q173H (on ENST00000368521 / NM_001297718.2; = p.Q139H on NM_015449.4) | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs752680591, COSV100634215; called by muse, mutect2, varscan2
- C4orf17 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770638582, COSV100430875; called by muse, mutect2, varscan2
- C5orf38 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs772380035, COSV100121673, COSV57412756, COSV57414154; called by muse, mutect2
- CACNA1S | c.5575G>C p.D1859H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100754879, COSV62943304; called by muse, mutect2, varscan2
- CCDC141 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs1436880675, COSV99836579; called by muse, mutect2, varscan2
- CCDC191 | c.2640G>C p.K880N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99878110; called by muse, mutect2, varscan2
- CCDC7 | c.3719T>C p.I1240T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.122); catalogued as COSV100178029; called by muse, mutect2, varscan2
- CDH4 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV100848662; called by muse, mutect2, varscan2
- CHAMP1 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100778773; called by muse, mutect2, varscan2
- CHD8 | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV101303100; called by muse, mutect2, varscan2
- CHSY1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99573797; called by muse, mutect2, varscan2
- CLIP2 | c.2089G>C p.A697P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99791341; called by muse, mutect2, varscan2
- COL1A2 | c.3568G>T p.A1190S | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV51957680, COSV99799279; called by muse, mutect2, varscan2
- COP1 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | catalogued as COSV100443092; called by muse, mutect2, varscan2
- CPB1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99294179; called by muse, mutect2, varscan2
- CPS1 | c.3647G>T p.S1216I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99242687; called by muse, mutect2, varscan2
- CREB3L3 | c.1209G>A p.W403* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV50236880; called by muse, mutect2, varscan2
- CSH1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100298298, COSV100298378; called by muse, mutect2, varscan2
- CSMD3 | c.9736G>T p.G3246* (on ENST00000297405 / NM_001363185.1; = p.G3077* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV52140831, COSV52319855, COSV99831037; called by muse, mutect2, varscan2
- CTDSP2 | c.677A>T p.H226L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101142985; called by muse, mutect2, varscan2
- CTNNA2 | c.1291-1G>C p.X431_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100560021; called by muse, mutect2
- CTR9 | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV100797326; called by muse, mutect2, varscan2
- CTTNBP2NL | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.793); catalogued as rs766592429, COSV54746883, COSV99599896; called by muse, mutect2, varscan2
- CUX1 | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV99471117; called by muse, varscan2
- CXCR5 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.1); catalogued as COSV99419042; called by muse, mutect2, varscan2
- CYLD | c.2426C>G p.S809* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as COSV100282358; called by muse, mutect2, varscan2
- DCC | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100499221; called by muse, mutect2, varscan2
- DCC | c.3971A>T p.E1324V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV101472687; called by muse, mutect2, varscan2
- DCHS1 | c.5033T>A p.V1678E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100201895; called by muse, mutect2, varscan2
- DDX10 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100489311; called by muse, mutect2, varscan2
- DDX60 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190396; called by muse, mutect2, varscan2
- DGAT2 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 62/219 reads (28%) | catalogued as COSV99929669; called by muse, mutect2, varscan2
- DLL1 | c.1400G>A p.C467Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816007; called by muse, mutect2
- DNAJC12 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV99830557; called by muse, mutect2, varscan2
- DOCK4 | c.5799dup p.K1934Qfs*18 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | catalogued as rs1175746870; called by pindel, varscan2
- DPP3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as rs199921998, COSV100291748; called by muse, mutect2, varscan2
- DPY19L2 | c.1826G>T p.W609L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100193185; called by muse, mutect2, varscan2
- EEFSEC | c.1152G>C p.L384F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV99630055; called by muse, mutect2, varscan2
- EIF2AK3 | c.3347A>T p.N1116I | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV100303638; called by muse, mutect2, varscan2
- ENOX1 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV54922741; called by muse, mutect2, varscan2
- EPHA5 | c.2958C>A p.F986L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV56680703, COSV99896424; called by muse, mutect2, varscan2
- ESAM | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.079); catalogued as COSV99631743; called by muse, mutect2, varscan2
- FAM89B | c.428C>G p.S143C (on ENST00000530349 / NM_001098785.2; = p.S130C on NM_152832.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100326092; called by muse, mutect2, varscan2
- FANCG | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV62721922; called by muse, mutect2, varscan2
- FAT4 | c.13378A>T p.T4460S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.848); catalogued as COSV100628137; called by muse, mutect2, varscan2
- FBXO5 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99999764; called by muse, mutect2, varscan2
- FCRL5 | c.2723T>C p.L908P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100708776; called by muse, mutect2
- FHOD3 | c.2791A>G p.R931G (on ENST00000359247 / NM_001281739.3; = p.R948G on NM_025135.5) | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99940811; called by muse, mutect2, varscan2
- FLOT1 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV99458140; called by muse, mutect2, varscan2
- FLT1 | c.3310C>A p.Q1104K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99151353; called by muse, mutect2, varscan2
- GDI2 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050306, COSV100051250; called by muse, mutect2, varscan2
- GGPS1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99270407; called by muse, mutect2, varscan2
- GIMAP8 | c.1265T>C p.M422T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100217469; called by muse, mutect2, varscan2
- GNS | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476057351, COSV99253722; called by muse, mutect2, varscan2
- GPR149 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV101078325; called by muse, mutect2, varscan2
- GRB14 | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV99813901; called by muse, mutect2, varscan2
- GZF1 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100582479, COSV57634875; called by muse, mutect2
- GZF1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454072446, COSV100582481; called by muse, mutect2, varscan2
- H4C11 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1561928472, COSV100747980; called by mutect2, varscan2
- H4C7 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1467169763, COSV99769064; called by muse, mutect2, varscan2
- HMGCLL1 | c.172G>C p.A58P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV51453829; called by muse, mutect2
- HNRNPC | c.784G>A p.E262K (on ENST00000420743; = p.E249K on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100193027; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768964788; called by muse, mutect2
- INCENP | c.1471C>G p.P491A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99610881; called by muse, mutect2, varscan2
- INIP | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV100954112; called by muse, mutect2, varscan2
- INKA2 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615791, COSV61877799; called by muse, mutect2, varscan2
- INO80B | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV99270447; called by muse, mutect2, varscan2
- INTS9 | c.1702A>G p.R568G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101273847; called by muse, mutect2, varscan2
- ITPKC | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99648629; called by muse, mutect2, varscan2
- JAK3 | c.2741T>G p.L914R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101512911; called by muse, varscan2
- KCNA1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230186; called by muse, mutect2, varscan2
- KCNA6 | c.1275C>A p.Y425* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | catalogued as COSV99768533; called by muse, mutect2, varscan2
- KCNH1 | c.2369T>A p.V790E (on ENST00000271751 / NM_172362.3; = p.V763E on NM_002238.4) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV99658519; called by muse, mutect2, varscan2
- KCNH8 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.653); catalogued as rs767497421, COSV60466316; called by muse, mutect2, varscan2
- KDM3A | c.2411C>G p.S804C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100460253; called by muse, mutect2, varscan2
- KEL | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs776109413, COSV100787003; called by muse, mutect2, varscan2
- KIF21B | c.4391C>T p.T1464M (on ENST00000422435 / NM_001252100.2; = p.T1451M on NM_017596.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.488); catalogued as rs146916477; called by muse, mutect2, varscan2
- KIF9 | c.1724C>T p.P575L (on ENST00000265529 / NM_001377474.1; = p.P510L on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV99646589; called by muse, mutect2, varscan2
- KLHDC2 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV100026943, COSV53586721; called by muse, mutect2, varscan2
- KMT2C | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100070366; called by muse, mutect2, varscan2
- KMT2D | c.7618C>T p.Q2540* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99979938; called by muse, mutect2
- KRBA2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100497641; called by muse, mutect2, varscan2
- KRTAP12-4 | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100552821; called by muse, mutect2, varscan2
- KY | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV101414969; called by muse, mutect2, varscan2
- L1CAM | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); catalogued as rs1557093565, COSV100649021; called by muse, mutect2, varscan2
- LAIR1 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57309556; called by muse, mutect2, varscan2
- LAMB4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV52733280; called by muse, mutect2, varscan2
- LMBRD1 | c.1360G>C p.A454P (on ENST00000649011; = p.A432P on NM_018368.4) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100992535; called by muse, mutect2, varscan2
- LRIT1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as rs750608437, COSV100928060; called by muse, mutect2, varscan2
- LRP12 | c.2375C>A p.S792Y | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV52625837, COSV99407511; called by muse, mutect2, varscan2
- LRP2 | c.6139A>G p.T2047A | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV99787637; called by muse, mutect2, varscan2
- LRP5 | c.3728A>G p.H1243R | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as COSV99591762; called by muse, mutect2, varscan2
- LRP6 | c.4795C>G p.H1599D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV99742969; called by muse, mutect2, varscan2
- LRPPRC | c.2948A>T p.E983V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99580374; called by muse, mutect2, varscan2
- LRRC31 | c.990G>C p.L330= | Splice Region (SNP) | VAF 26/110 reads (24%) | catalogued as COSV52980513, COSV99246569; called by muse, mutect2, varscan2
- LRRIQ1 | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101279979; called by muse, mutect2, varscan2
- MACROD2 | c.1060C>T p.H354Y (on ENST00000642719; = p.H326Y on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.211); catalogued as COSV99429907; called by muse, mutect2, varscan2
- MAGEA4 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 75/123 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); catalogued as COSV99367421; called by muse, mutect2, varscan2
- MAP3K5 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100752674; called by muse, mutect2, varscan2
- MCF2L2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV100192054, COSV61061888; called by muse, mutect2, varscan2
- MED12L | c.5677C>G p.R1893G | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.982); catalogued as COSV99852497; called by muse, mutect2, varscan2
- MEIS3 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as rs754981542, COSV58984064; called by muse, mutect2, varscan2
- METTL24 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.696); catalogued as COSV100133246; called by muse, mutect2, varscan2
- MIB1 | c.2720G>C p.R907T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.855); catalogued as COSV99838600; called by muse, mutect2, varscan2
- MLLT1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs139774005; called by muse, mutect2, varscan2
- MORN1 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087817; called by muse, mutect2, varscan2
- MS4A3 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99614660; called by muse, mutect2, varscan2
- MSRB2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100919700; called by muse, mutect2, varscan2
- MTHFD1L | c.1945-1G>C p.X649_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100944987, COSV66226722; called by muse, mutect2, varscan2
- MUC16 | c.3467C>G p.S1156* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV101199346; called by muse, mutect2, varscan2
- MYCN | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99808197; called by muse, mutect2, varscan2
- MYH13 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs1429083876, COSV52822325, COSV99353394; called by muse, mutect2, varscan2
- MYO9B | c.2038G>C p.V680L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101261485, COSV101261804; called by muse, mutect2, varscan2
- NCF4 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV99957247; called by muse, mutect2, varscan2
- NFKBIZ | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV100397010; called by muse, mutect2
- NKD2 | c.870T>A p.D290E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV99723989; called by muse, mutect2
- NLRP12 | c.2322G>T p.R774S | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100145117; called by muse, mutect2, varscan2
- NPC1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as COSV99341127; called by muse, mutect2, varscan2
- NPHS1 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV100799737; called by muse, mutect2, varscan2
- NPY5R | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100642737, COSV58450937; called by muse, mutect2, varscan2
- NT5C3A | c.307+1G>A p.X103_splice (on ENST00000610140 / NM_001374335.1; = p.X69_splice on NM_016489.13) | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99641054; called by muse, mutect2, varscan2
- NUDT2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100663537; called by muse, mutect2
- ODF2 | c.144G>A p.M48I (on ENST00000434106 / NM_153433.2; = p.M43I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.262); catalogued as COSV100654537; called by muse, mutect2, varscan2
- OR10J3 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs1191171207, COSV100171692, COSV99046059; called by muse, mutect2, varscan2
- OR13H1 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV100088199; called by muse, mutect2, varscan2
- OR1A1 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.05); catalogued as COSV100410741; called by muse, mutect2
- OR1M1 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV101447555; called by muse, mutect2, varscan2
- OR2B11 | c.846T>A p.Y282* | Nonsense Mutation (SNP) | VAF 39/265 reads (15%) | catalogued as COSV59509815; called by muse, mutect2, varscan2
- OR2F1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101231299, COSV67332134; called by muse, mutect2, varscan2
- OR2M4 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs371284889, COSV60707981; called by muse, varscan2
- OR2M4 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100140963, COSV100141105, COSV60709407; called by muse, varscan2
- OR52E4 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100389209; called by muse, mutect2, varscan2
- OR5AS1 | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100546233; called by muse, mutect2, varscan2
- OR5H2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100788696, COSV62351571; called by muse, mutect2, varscan2
- OR5L2 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs202214388, COSV65723601, COSV65724678; called by muse, mutect2, varscan2
- OR6K2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as COSV100656662, COSV100656758; called by muse, mutect2, varscan2
- OR6Y1 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100225327; called by muse, mutect2
- OSGIN2 | c.742C>G p.H248D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.173); catalogued as rs776654382, COSV99858191; called by muse, mutect2, varscan2
- PARD3B | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559462930, COSV100593017; called by muse, mutect2, varscan2
- PAX2 | c.733G>A p.D245N (on ENST00000428433 / NM_003987.5; = p.D222N on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/253 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as rs1435705672, COSV100695120; called by muse, mutect2, varscan2
- PCDHGA5 | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs539434078, COSV99535398; called by muse, mutect2, varscan2
- PCDHGB1 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); catalogued as COSV99535405; called by muse, mutect2, varscan2
- PDE1C | c.2021C>G p.P674R | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100372053; called by muse, mutect2, varscan2
- PDE1C | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs762050534, COSV58520743; called by muse, mutect2, varscan2
- PDE1C | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765961590, COSV58504744; called by muse, mutect2, varscan2
- PGGHG | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs369157724; called by muse, mutect2, varscan2
- PHACTR3 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV63027243; called by muse, mutect2, varscan2
- PIK3R3 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776413265, COSV53105515, COSV99423086; called by muse, mutect2, varscan2
- PLCL2 | c.1536G>T p.E512D (on ENST00000615277 / NM_001144382.2; = p.E386D on NM_015184.5) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV101196655; called by muse, mutect2, varscan2
- PLEKHA6 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369190008; called by muse, varscan2
- PLXDC2 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.193); catalogued as COSV101022877; called by muse, mutect2, varscan2
- PNPLA5 | c.1200-1G>A p.X400_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99336577; called by muse, mutect2, varscan2
- POGLUT1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs779712185, COSV99809526; called by muse, mutect2, varscan2
- PPFIA2 | c.2911C>A p.P971T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100332740; called by muse, mutect2, varscan2
- PPFIA2 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100332743, COSV61058087; called by muse, mutect2, varscan2
- PRDM9 | c.970del p.D324Mfs*84 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | catalogued as COSV104393208; called by mutect2, pindel, varscan2
- PRKCG | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV54726488, COSV99668833; called by muse, mutect2, varscan2
- PRKRIP1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.137); catalogued as COSV100700335; called by muse, mutect2
- PSMA1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV67166126; called by muse, mutect2, varscan2
- PSMA3 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV99373396; called by muse, mutect2, varscan2
- PTPN18 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs371739121, COSV51559036; called by muse, mutect2, varscan2
- PTPRM | c.2744G>A p.W915* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100156464; called by muse, mutect2, varscan2
- QKI | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99274785; called by muse, mutect2, varscan2
- RAC2 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as rs754120892, COSV99969453; called by muse, mutect2, varscan2
- RAET1L | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.058); catalogued as COSV53953966; called by muse, mutect2, varscan2
- RAPGEF6 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 42/145 reads (29%) | catalogued as COSV99726095; called by muse, mutect2, varscan2
- RELN | c.9409C>G p.H3137D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100633238; called by muse, mutect2, varscan2
- RFX4 | c.523G>A p.G175R (on ENST00000392842 / NM_213594.3; = p.G81R on NM_032491.6) | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57583296; called by muse, mutect2, varscan2
- RGS17 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV99242743; called by muse, mutect2, varscan2
- RIMS2 | c.4309C>A p.P1437T (on ENST00000666250 / NM_001348490.2; = p.P1008T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV99166213; called by muse, mutect2, varscan2
- RP1 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV55126060, COSV99607016; called by muse, mutect2, varscan2
- RTEL1 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100541684; called by muse, mutect2, varscan2
- RUBCN | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56373869, COSV99583762; called by muse, mutect2, varscan2
- SERINC1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs745408354, COSV100305141, COSV60102364; called by muse, mutect2, varscan2
- SGCZ | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101168382, COSV66016108; called by muse, mutect2, varscan2
- SGK3 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs780326958, COSV100616647; called by muse, mutect2, varscan2
- SH3GL3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs767942529, COSV100196436; called by muse, mutect2, varscan2
- SHANK1 | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.127); catalogued as COSV53255058; called by muse, mutect2, varscan2
- SHANK2 | c.3686A>T p.E1229V | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99573285; called by muse, mutect2, varscan2
- SLC17A1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199627788, COSV99765691; called by muse, mutect2, varscan2
- SLC17A3 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1367958951, COSV100399156; called by muse, mutect2, varscan2
- SLC25A32 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52569146, COSV99884352; called by muse, mutect2, varscan2
- SLC38A8 | c.1232G>A p.W411* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs1160888070, COSV100230410, COSV55308875; called by muse, mutect2, varscan2
- SLC4A11 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV101195929; called by muse, mutect2, varscan2
- SLC6A12 | c.49T>A p.W17R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV100675047; called by muse, mutect2, varscan2
- SLC9C1 | c.497G>C p.S166T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.671); catalogued as COSV99997712; called by muse, mutect2, varscan2
- SLCO3A1 | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100575224; called by muse, mutect2, varscan2
- SLX4IP | c.539C>G p.T180R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV57943602, COSV57952245; called by muse, mutect2, varscan2
- SMC6 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100704989; called by muse, mutect2, varscan2
- SOBP | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433012; called by muse, mutect2, varscan2
- SORCS1 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV99545196; called by muse, mutect2
- SPANXN2 | c.78+1G>T p.X26_splice | Splice Site (SNP) | VAF 64/120 reads (53%) | catalogued as rs1466584279, COSV100979870; called by muse, mutect2, varscan2
- SPATA31E1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100350255; called by muse, mutect2, varscan2
- SPTBN4 | c.2677T>C p.C893R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100150582; called by muse, mutect2, varscan2
- STARD6 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100323407; called by muse, mutect2, varscan2
- STOX1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100057751; called by muse, mutect2, varscan2
- STXBP5L | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56541924; called by muse, mutect2
- SULF1 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV52677960, COSV99482748; called by muse, mutect2, varscan2
- SURF2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1182952634, COSV64332277, COSV64332613; called by muse, mutect2, varscan2
- SYT11 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1447949693, COSV100851296; called by muse, varscan2
- TAF5L | c.1327A>T p.T443S | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99272983; called by muse, mutect2
- TAS2R10 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs1463665443, COSV99555495; called by muse, mutect2, varscan2
- TBXAS1 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695112; called by muse, mutect2, varscan2
- TCF21 | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV99399605; called by muse, mutect2, varscan2
- TCTE1 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs748939646, COSV101025380; called by muse, mutect2, varscan2
- TECTB | c.363C>A p.C121* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV101027668; called by muse, mutect2, varscan2
- TENM1 | c.7162C>G p.P2388A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100949695; called by muse, mutect2, varscan2
- TENM1 | c.2786C>G p.A929G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100949699, COSV100950025; called by muse, mutect2, varscan2
- TET2 | c.2251A>T p.K751* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99482211; called by muse, mutect2, varscan2
- TMEM132E | c.1966C>T p.P656S (on ENST00000321639; = p.P746S on NM_001304438.2) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1049003965, COSV100396096; called by muse, mutect2, varscan2
- TMEM45A | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV100058280; called by muse, mutect2, varscan2
- TMEM59L | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV99450147; called by muse, mutect2, varscan2
- TNFAIP8 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV57229520, COSV99174250; called by muse, mutect2, varscan2
- TOGARAM1 | c.1271G>C p.R424P | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100753062; called by muse, mutect2, varscan2
- TPPP2 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100409528, COSV58794937; called by muse, mutect2, varscan2
- TRIM60 | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV100593980; called by muse, mutect2, varscan2
- TROAP | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 43/204 reads (21%) | catalogued as COSV99226789; called by muse, mutect2, varscan2
- TRPM7 | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.996); catalogued as COSV100539696; called by muse, mutect2, varscan2
- TRRAP | c.7014G>C p.M2338I (on ENST00000359863 / NM_001244580.1; = p.M2320I on NM_003496.3) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV100722311; called by muse, mutect2, varscan2
- TTC24 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as COSV100964322; called by muse, mutect2, varscan2
- TTK | c.1776A>T p.E592D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100036175; called by muse, mutect2, varscan2
- TTN | c.23458T>A p.L7820M (on ENST00000591111; = p.L6893M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | PolyPhen probably damaging (0.976); catalogued as COSV100604997; called by muse, mutect2, varscan2
- TTN | c.4919C>A p.T1640N (on ENST00000591111; = p.T1594N on NM_003319.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | PolyPhen probably damaging (0.997); catalogued as COSV100604998; called by muse, mutect2, varscan2
- TULP1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs1171311001, COSV100004047; called by muse, mutect2, varscan2
- UPF1 | c.1201G>A p.E401K (on ENST00000599848 / NM_001297549.2; = p.E390K on NM_002911.4) | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV53199015, COSV53200443, COSV99439268; called by muse, mutect2, varscan2
- USH2A | c.6184C>T p.P2062S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100232713; called by muse, mutect2, varscan2
- USH2A | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.201); catalogued as COSV100232717, COSV56448781; called by muse, mutect2, varscan2
- USP11 | c.2590G>T p.E864* (on ENST00000218348; = p.E821* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV54475774, COSV99510855; called by muse, varscan2
- USP17L2 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100414563, COSV61557149; called by muse, mutect2, varscan2
- USP36 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 53/125 reads (42%) | catalogued as COSV100361409; called by muse, mutect2, varscan2
- UTP20 | c.7351A>G p.I2451V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99881339; called by muse, mutect2, varscan2
- VCX | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV100406250; called by muse, mutect2, varscan2
- WNK1 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100266977; called by muse, mutect2
- WNK3 | c.4136A>T p.Q1379L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100671154; called by muse, mutect2, varscan2
- ZFHX4 | c.3866T>C p.M1289T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV99261157; called by muse, mutect2
- ZIC4 | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as COSV101267909; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2327A>G p.H776R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100460114; called by muse, mutect2, varscan2
- ZNF274 | c.474G>T p.E158D (on ENST00000610905; = p.E53D on NM_016324.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV100464954; called by muse, mutect2, varscan2
- ZNF341 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV100677818; called by muse, mutect2, varscan2
- ZNF347 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100498231; called by muse, mutect2, varscan2
- ZNF358 | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900524; called by muse, mutect2, varscan2
- ZNF516 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101487245; called by muse, mutect2
- ZNF546 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV100713407; called by muse, mutect2, varscan2
- ZNF570 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356119; called by muse, mutect2, varscan2
- ZNF583 | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99382058; called by muse, mutect2, varscan2
- ZNF790 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as COSV100764806; called by muse, mutect2, varscan2
- ZRANB3 | c.2566C>G p.L856V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV99923275; called by muse, mutect2, varscan2
- AKAP9 | c.6460dup p.T2154Nfs*6 (on ENST00000359028; = p.T2122Nfs*6 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 25/156 reads (16%) | called by mutect2, pindel, varscan2
- CALB1 | c.595del p.D199Ifs*8 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- CDKN2A | c.161dup p.M54Ifs*66 | Frame Shift Ins (INS) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4260G>T p.L1420F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FDXR | c.446_459del p.P149Rfs*13 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, pindel, varscan2
- KCNK16 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MAGEA9B | c.869T>A p.V290D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by mutect2, varscan2
- MAGEB6B | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NBN | c.2121del p.L708* | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | called by mutect2, pindel, varscan2
- OR51V1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PIGW | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- SNX18 | c.877_903del p.K293_V301del | In Frame Del (DEL) | VAF 16/106 reads (15%) | called by mutect2, pindel
- STXBP5L | c.3451G>T p.G1151* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- TPTE | c.1089+1G>A p.X363_splice (on ENST00000618007 / NM_199261.4; = p.X345_splice on NM_199259.4) | Splice Site (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF750 | c.1317_1324del p.S440Gfs*17 | Frame Shift Del (DEL) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- A2ML1 | c.936C>T p.I312= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as COSV100228785; called by muse, mutect2, varscan2
- ADAMTS12 | c.2706G>T p.G902= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV100710648; called by muse, mutect2, varscan2
- ADGRL4 | c.909G>A p.K303= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV66067779; called by muse, mutect2
- ALPK3 | c.3096G>A p.L1032= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV99360661; called by muse, mutect2, varscan2
- ASXL3 | c.3393T>C p.P1131= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs895569374, COSV99324300; called by muse, mutect2, varscan2
- BMPER | c.879G>T p.V293= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV99779374; called by muse, mutect2, varscan2
- BPIFB4 | c.690G>A p.V230= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100971483; called by muse, mutect2, varscan2
- C1S | c.1992C>G p.L664= | Silent (SNP) | VAF 57/370 reads (15%) | catalogued as rs782399643, COSV100196503; called by muse, mutect2, varscan2
- CABP2 | c.324G>A p.R108= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV99590781; called by muse, mutect2, varscan2
- CBLN2 | c.651G>T p.S217= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99504278; called by muse, mutect2, varscan2
- CCDC27 | c.1935C>T p.F645= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99622331; called by muse, mutect2, varscan2
- CEP135 | c.492T>C p.I164= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99954310; called by muse, mutect2, varscan2
- CHD9 | c.6747T>C p.G2249= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99529024; called by muse, mutect2, varscan2
- CLCN4 | c.1119C>A p.V373= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as COSV101073758; called by muse, mutect2, varscan2
- CR2 | c.435C>A p.T145= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100889591; called by muse, mutect2, varscan2
- DCAF4L1 | c.486G>A p.S162= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV100295655; called by muse, mutect2, varscan2
- DDC | c.99G>T p.V33= | Silent (SNP) | VAF 56/296 reads (19%) | catalogued as COSV100779206; called by muse, mutect2, varscan2
- DNAH8 | c.11124A>T p.S3708= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100544341; called by muse, mutect2, varscan2
- DOCK2 | c.4911G>A p.L1637= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99911495; called by muse, mutect2, varscan2
- DSCAM | c.3009C>A p.V1003= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV101259750; called by muse, mutect2, varscan2
- EDIL3 | c.1062G>A p.R354= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99675771; called by muse, mutect2, varscan2
- EIF2AK1 | c.1782G>A p.Q594= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99551784; called by muse, mutect2, varscan2
- EIF3B | c.1182G>A p.L394= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100703645; called by muse, mutect2, varscan2
- FCRLA | c.810C>T p.N270= (on ENST00000367959; = p.N247= on NM_032738.4) | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV99375885; called by muse, mutect2, varscan2
- FOXN4 | c.657C>T p.I219= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100142122; called by muse, mutect2, varscan2
- FUT9 | c.1023G>C p.V341= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100132816, COSV100133391, COSV56153608; called by muse, mutect2, varscan2
- FYCO1 | c.2226G>A p.Q742= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs1419593816, COSV99945475; called by muse, mutect2, varscan2
- GBX2 | c.825C>G p.T275= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs779554048, COSV100103508; called by muse, mutect2, varscan2
- GPR37 | c.207C>T p.A69= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100390721; called by muse, mutect2, varscan2
- GRM7 | c.1776G>C p.V592= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100736127; called by muse, mutect2, varscan2
- HLA-F | c.789G>A p.Q263= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99465886; called by muse, mutect2, varscan2
- IL13RA2 | c.147C>T p.L49= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99682873, COSV99682992; called by muse, mutect2, varscan2
- INSC | c.1593C>A p.A531= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV65412693, COSV65413083; called by muse, mutect2, varscan2
- IRX4 | c.630G>A p.P210= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs763072295, COSV51471275; called by muse, mutect2, varscan2
- KAT5 | c.432C>T p.H144= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs552339924, COSV100383880; called by muse, mutect2, varscan2
- KCNA4 | c.1473C>G p.L491= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs745957532, COSV100068815, COSV100068832; called by muse, mutect2, varscan2
- KCNC2 | c.1548C>A p.A516= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as COSV100128589; called by muse, mutect2, varscan2
- KCND2 | c.240T>A p.T80= | Silent (SNP) | VAF 43/218 reads (20%) | catalogued as COSV100474976; called by muse, mutect2, varscan2
- KDELR3 | c.207C>G p.L69= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV99318156; called by muse, mutect2, varscan2
- KIR3DL1 | c.1233C>A p.I411= | Silent (SNP) | VAF 68/341 reads (20%) | catalogued as COSV58493421; called by muse, mutect2, varscan2
- KLK1 | c.69C>A p.S23= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100032668; called by muse, mutect2, varscan2
- MAP1A | c.645C>T p.L215= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1289226233, COSV100288433; called by muse, mutect2, varscan2
- MAST4 | c.1023G>A p.E341= (on ENST00000403625 / NM_001164664.2; = p.E152= on NM_015183.3) | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV99843737; called by muse, mutect2, varscan2
- MICAL2 | c.4158C>T p.I1386= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs377505982, COSV56288884; called by muse, mutect2, varscan2
- MROH2B | c.843C>A p.L281= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV68181942, COSV68183788, COSV68191216; called by muse, mutect2
- MSLN | c.78C>T p.F26= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV101242355; called by muse, mutect2, varscan2
- MTHFD1L | c.2652C>T p.L884= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100944989; called by muse, mutect2, varscan2
- MYOC | c.552G>A p.Q184= | Silent (SNP) | VAF 65/424 reads (15%) | catalogued as COSV99231425; called by muse, mutect2, varscan2
- NES | c.3681G>T p.P1227= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV63960809, COSV63961748; called by muse, mutect2, varscan2
- NPAP1 | c.534C>T p.T178= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1289343982, COSV100275140; called by muse, mutect2, varscan2
- OR11H6 | c.216G>A p.R72= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100209768; called by muse, mutect2, varscan2
- OR2M5 | c.636A>G p.A212= | Silent (SNP) | VAF 73/425 reads (17%) | catalogued as COSV100822791; called by muse, mutect2, varscan2
- OR5A1 | c.834T>C p.S278= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as COSV100118335; called by muse, mutect2, varscan2
- OR5L2 | c.666C>T p.L222= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs756858065, COSV101004285; called by muse, mutect2, varscan2
- OSBPL11 | c.1011G>C p.A337= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs774027543, COSV99954103, COSV99954108; called by muse, mutect2, varscan2
- OVCH1 | c.2076A>G p.L692= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs778323105, COSV100548432; called by muse, mutect2, varscan2
- PAMR1 | c.273C>T p.C91= | Silent (SNP) | VAF 49/220 reads (22%) | catalogued as COSV99552436; called by muse, mutect2, varscan2
- PITPNA | c.270T>G p.A90= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100541458; called by muse, mutect2, varscan2
- PLEKHA6 | c.1188C>T p.F396= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99691837; called by muse, mutect2, varscan2
- POTEH | c.126C>T p.N42= | Silent (SNP) | VAF 64/253 reads (25%) | catalogued as rs778568056, COSV100624878; called by muse, varscan2
- PRAMEF2 | c.54G>T p.L18= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV53574495, COSV99535089; called by muse, mutect2, varscan2
- PSG7 | c.414C>T p.F138= | Silent (SNP) | VAF 66/346 reads (19%) | catalogued as COSV101343222; called by muse, mutect2, varscan2
- PSMD13 | c.600G>A p.L200= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1219753443, COSV100728784; called by muse, mutect2, varscan2
- RAI1 | c.2251C>T p.L751= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV99883793; called by muse, mutect2, varscan2
- RIMS1 | c.3444C>G p.P1148= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99325739, COSV99328597; called by muse, mutect2, varscan2
- RYR2 | c.219C>G p.L73= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as COSV100769400; called by muse, mutect2, varscan2
- RYR2 | c.900C>A p.V300= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as COSV63669049; called by muse, mutect2, varscan2
- SLC9A7 | c.1068C>T p.F356= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs1479432724, COSV100091912; called by muse, mutect2, varscan2
- SPAM1 | c.267A>G p.T89= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV99772925; called by muse, mutect2, varscan2
- SYNE1 | c.14271C>G p.T4757= (on ENST00000367255 / NM_182961.4; = p.T4686= on NM_033071.3) | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV99559866; called by muse, mutect2, varscan2
- TRIM24 | c.2307G>A p.Q769= (on ENST00000343526 / NM_015905.3; = p.Q735= on NM_003852.4) | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV100630832; called by muse, mutect2, varscan2
- TTI1 | c.234C>T p.L78= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as COSV100989620; called by muse, mutect2, varscan2
- UTP20 | c.2124G>A p.Q708= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV55381545, COSV99881336; called by muse, mutect2, varscan2
- VAMP8 | c.222G>C p.V74= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as COSV99809142; called by muse, mutect2, varscan2
- VAX1 | c.132C>G p.L44= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV53330302; called by muse, mutect2, varscan2
- ZNF335 | c.660C>T p.P220= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100532861; called by muse, mutect2, varscan2
- AKT2 | c.*235G>T | 3'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs772124752, COSV100251535; called by muse, mutect2
- ARHGEF25 | chr12:57610267 G>A | 5'Flank (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99677810; called by muse, mutect2
- DCHS2 | n.6223G>A | RNA (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100601531; called by muse, mutect2, varscan2
- LEKR1 | c.*530T>C | 3'UTR (SNP) | VAF 24/141 reads (17%) | catalogued as COSV100738811; called by muse, mutect2, varscan2
- MIR205 | chr1:209430439 C>G | 5'Flank (SNP) | VAF 23/129 reads (18%) | catalogued as rs375225553; called by muse, mutect2, varscan2
- NXF5 | n.645G>T | RNA (SNP) | VAF 26/63 reads (41%) | catalogued as COSV53790270, COSV99534275; called by muse, mutect2, varscan2
- RPL23AP42 | n.198C>A | RNA (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- SLC22A20P | n.942G>A | RNA (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- VN1R10P | n.521T>C | RNA (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- ZNF618 | c.755-527G>C | Intron (SNP) | VAF 12/35 reads (34%) | catalogued as COSV99929840; called by muse, mutect2, varscan2
- ZNF99 | c.*561C>T | 3'UTR (SNP) | VAF 11/57 reads (19%) | catalogued as rs1259094262, COSV68057286, COSV68057378; called by muse, mutect2, varscan2
